Somatic mutation profile of tumor specimen 0DT3UF from CCDI case PBCIAS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin of trunk; Age at diagnosis: 10.9 years (3,985 days).
Specimen 0DT3UF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 82be3c36-f1c8-4131-9e6f-4a3a3b6927d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT3UO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af9bf7a0-7b0c-40f8-83a8-0fa98b086119

The open-access MAF lists 212 somatic variants for this specimen: 124 protein-altering or splice-affecting, 54 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 54, Intron 19, Nonsense Mutation 9, 3'UTR 5, Splice Site 4, 5'UTR 4, 5'Flank 4, Splice Region 2, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SYNE1 | c.9208C>T p.R3070* (on ENST00000367255 / NM_182961.4; = p.R3077* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 196/1574 reads (12%) | catalogued as rs549779256, COSV54895674; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2816G>A p.G939E | Missense Mutation (SNP) | VAF 76/703 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV55953525, COSV55964894; called by muse, mutect2, varscan2
- ACTR1B | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 78/708 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs191369953; called by muse, varscan2
- ACTR1B | c.843C>A p.F281L | Missense Mutation (SNP) | VAF 64/556 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV56704524; called by muse, varscan2
- ADAM29 | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 120/951 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.133); catalogued as COSV63666072; called by muse, mutect2, varscan2
- ADARB2 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 23/368 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.87); catalogued as rs755854917; called by muse, mutect2
- ADH1B | c.754C>T p.Q252* | Nonsense Mutation (SNP) | VAF 122/1350 reads (9%) | catalogued as COSV100520894; called by muse, mutect2
- ANO3 | c.2050C>T p.P684S | Missense Mutation (SNP) | VAF 71/829 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs754335144; called by muse, mutect2
- ARHGAP29 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 162/1313 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.051); catalogued as rs770643185, COSV53109092; called by muse, mutect2, varscan2
- ATF6B | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 50/571 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64352364; called by muse, mutect2
- ATP8A1 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 155/1285 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs1217699790, COSV52531992; called by muse, mutect2, varscan2
- BLNK | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 62/644 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs781793117, COSV99814060; called by muse, mutect2, varscan2
- BRINP2 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 47/389 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV64177086, COSV64178707; called by muse, mutect2, varscan2
- C16orf96 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.253); catalogued as rs1277387366, COSV101474583; called by muse, mutect2
- CA10 | c.151G>C p.G51R | Missense Mutation (SNP) | VAF 127/1006 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53373561; called by muse, mutect2, varscan2
- CASP12 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 99/974 reads (10%) | catalogued as rs746375604, COSV65259724; called by muse, mutect2, varscan2
- CCDC190 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 75/544 reads (14%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV63362644; called by muse, mutect2, varscan2
- CD46 | c.735A>T p.K245N | Missense Mutation (SNP) | VAF 85/794 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1048263862, COSV59733489; called by muse, mutect2, varscan2
- CEP44 | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 69/811 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1396163897; called by muse, mutect2
- CHGA | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 66/666 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1310251280, COSV50894165; called by muse, mutect2, varscan2
- CNGA2 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 93/374 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs959972258, COSV61706168; called by muse, mutect2, varscan2
- CSMD1 | c.5380G>A p.D1794N (on ENST00000520002; = p.D1793N on NM_033225.6) | Missense Mutation (SNP) | VAF 76/677 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.997); catalogued as rs745955541, COSV59286062; called by muse, mutect2, varscan2
- DENND11 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 116/898 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV72097697; called by muse, varscan2
- DGAT2L6 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 118/554 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs369585641, COSV60717250; called by muse, mutect2, varscan2
- DLG5 | c.5675C>T p.A1892V | Missense Mutation (SNP) | VAF 42/632 reads (7%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.544); catalogued as rs763791040; called by muse, mutect2
- DNAH5 | c.11212-1G>A p.X3738_splice | Splice Site (SNP) | VAF 55/459 reads (12%) | catalogued as COSV99454197; called by muse, mutect2, varscan2
- DNAH9 | c.1067G>A p.G356E | Missense Mutation (SNP) | VAF 97/779 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.158); catalogued as rs756842427, COSV52375746; called by muse, mutect2, varscan2
- DOCK2 | c.2399C>A p.P800Q | Missense Mutation (SNP) | VAF 120/1033 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56983648; called by muse, mutect2, varscan2
- DOCK8 | c.2629C>T p.P877S | Missense Mutation (SNP) | VAF 70/608 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs1446875420; called by muse, mutect2, varscan2
- FCRL4 | c.796G>A p.V266M | Missense Mutation (SNP) | VAF 84/732 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.271); catalogued as COSV54862078; called by muse, mutect2, varscan2
- FLG | c.7558G>A p.D2520N | Missense Mutation (SNP) | VAF 40/288 reads (14%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs866141505, COSV64236630; called by muse, mutect2
- GTF3C1 | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 97/716 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV62240484; called by muse, mutect2, varscan2
- HTR1D | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 54/567 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1180647296; called by muse, mutect2
- IKBKB | c.1397C>T p.S466F | Missense Mutation (SNP) | VAF 74/760 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV100645812; called by muse, mutect2
- IPCEF1 | c.518C>T p.S173F | Missense Mutation (SNP) | VAF 76/631 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as rs1377979624, COSV54544646; called by muse, mutect2, varscan2
- KCNH2 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as CM057137; called by muse, mutect2, varscan2
- KIFC2 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as rs979562309; called by muse, mutect2, varscan2
- KLF4 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 47/272 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.155); catalogued as rs965501282, COSV65928535; called by muse, mutect2, varscan2
- LKAAEAR1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 42/398 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); catalogued as rs973442567; called by muse, mutect2
- LZTS3 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 63/559 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs143536484; called by muse, mutect2, varscan2
- MARCO | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 152/1176 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.284); catalogued as rs771963608, COSV59056016; called by muse, mutect2, varscan2
- METAP1 | c.959C>T p.S320L | Missense Mutation (SNP) | VAF 90/991 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs750260867; called by muse, mutect2
- MLH1 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 104/772 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs63750760, CM022425, COSV51614892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTERF2 | c.649C>T p.P217S | Missense Mutation (SNP) | VAF 99/923 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755108452; called by muse, mutect2, varscan2
- NRAP | c.4267G>A p.G1423R (on ENST00000359988 / NM_001322945.2; = p.G1388R on NM_006175.4) | Missense Mutation (SNP) | VAF 158/1210 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs767729370; called by muse, mutect2, varscan2
- NUBPL | c.143G>A p.R48K | Missense Mutation (SNP) | VAF 122/1077 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs767048367; called by muse, mutect2, varscan2
- OR10H5 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 81/650 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.052); catalogued as COSV100454665; called by muse, mutect2, varscan2
- OR1M1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751140480, COSV70036846; called by muse, mutect2, varscan2
- OR1S2 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 94/974 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as COSV56919698, COSV56921494; called by muse, mutect2
- OR4A5 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 85/767 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.295); catalogued as rs770249402, COSV60521838; called by muse, mutect2, varscan2
- PADI3 | c.1650G>A p.W550* | Nonsense Mutation (SNP) | VAF 37/349 reads (11%) | catalogued as rs766642983; called by muse, mutect2, varscan2
- PHACTR4 | c.1834C>T p.R612C (on ENST00000373839 / NM_001350159.2; = p.R622C on NM_023923.4) | Missense Mutation (SNP) | VAF 103/1139 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs76093678, COSV65783180; called by muse, mutect2
- PRND | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 87/782 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.158); catalogued as COSV99999375; called by muse, mutect2, varscan2
- PTEN | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 148/1178 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs905615413, COSV64294248; called by muse, mutect2, varscan2
- PTPRD | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 174/1426 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV61934634, COSV61991481; called by muse, mutect2, varscan2
- PTPRT | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 95/782 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as rs724159835, COSV61966941; called by muse, mutect2, varscan2
- PZP | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 113/1092 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as COSV54362514; called by muse, mutect2, varscan2
- RAB11FIP1 | c.1019C>T p.P340L | Missense Mutation (SNP) | VAF 84/732 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs570777718; called by muse, mutect2, varscan2
- RASL11A | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 69/576 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54081352; called by muse, mutect2, varscan2
- RECQL4 | c.3185G>A p.R1062Q | Missense Mutation (SNP) | VAF 54/503 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.263); catalogued as rs558058260, COSV56739650, COSV56741833; ClinVar: uncertain significance; called by mutect2, varscan2
- RNF17 | c.2939G>A p.R980Q | Missense Mutation (SNP) | VAF 111/893 reads (12%) | SIFT tolerated (0.91); PolyPhen benign (0.029); catalogued as rs768777758, COSV99693307; called by muse, mutect2, varscan2
- RPTOR | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 83/756 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.061); catalogued as COSV60806220; called by muse, mutect2, varscan2
- SRCAP | c.6889C>T p.R2297W | Missense Mutation (SNP) | VAF 43/496 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99351802; called by muse, mutect2
- STARD9 | c.12247C>T p.Q4083* | Nonsense Mutation (SNP) | VAF 48/580 reads (8%) | catalogued as rs780496812; called by muse, mutect2
- STXBP5L | c.1732C>T p.P578S | Missense Mutation (SNP) | VAF 128/1184 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV56502103, COSV56542218; called by muse, mutect2, varscan2
- TENM3 | c.5255G>A p.R1752Q | Missense Mutation (SNP) | VAF 87/877 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs755116190, COSV69312770; called by muse, mutect2, varscan2
- TEX15 | c.7615G>A p.D2539N (on ENST00000256246; = p.D2922N on NM_001350162.2) | Missense Mutation (SNP) | VAF 100/926 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.106); catalogued as COSV56353718, COSV99821854; called by muse, mutect2, varscan2
- TOPAZ1 | c.3469C>T p.P1157S | Missense Mutation (SNP) | VAF 98/996 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.656); catalogued as rs267599832; called by muse, mutect2
- TTLL2 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 138/1184 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs374723694; called by muse, mutect2, varscan2
- VARS2 | c.2182C>T p.Q728* | Nonsense Mutation (SNP) | VAF 65/682 reads (10%) | catalogued as rs1010370253; called by muse, mutect2
- WDR33 | c.2687C>T p.S896F | Missense Mutation (SNP) | VAF 60/723 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV59247820; called by muse, mutect2
- ZBTB21 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 53/522 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs952197943; called by muse, mutect2, varscan2
- ZNF729 | c.292C>T p.Q98* | Nonsense Mutation (SNP) | VAF 142/1333 reads (11%) | catalogued as rs1401627133, COSV62603323; called by muse, mutect2, varscan2
- AC008397.2 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 37/414 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.155); called by muse, mutect2
- ACTRT1 | c.879A>T p.K293N | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTSL2 | c.2687C>T p.P896L | Missense Mutation (SNP) | VAF 35/344 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANAPC1 | c.3017G>T p.G1006V | Missense Mutation (SNP) | VAF 44/596 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ATP5MG | c.213+6C>T | Splice Region (SNP) | VAF 75/691 reads (11%) | called by muse, mutect2, varscan2
- BMP7 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 65/592 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- C4orf51 | c.59C>T p.S20F | Missense Mutation (SNP) | VAF 156/1411 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CETP | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 58/455 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CFAP46 | c.4289C>T p.P1430L | Missense Mutation (SNP) | VAF 76/966 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2
- CFHR4 | c.472G>A p.A158T (on ENST00000367416 / NM_001201551.2; = p.A159T on NM_001201550.3) | Missense Mutation (SNP) | VAF 101/1036 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- CHP2 | c.147G>A p.M49I | Missense Mutation (SNP) | VAF 60/532 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- COL11A1 | c.5275-2A>T p.X1759_splice | Splice Site (SNP) | VAF 70/780 reads (9%) | called by muse, mutect2
- DIDO1 | c.3703C>T p.P1235S | Missense Mutation (SNP) | VAF 84/854 reads (10%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- DLG1 | c.1411C>T p.R471C | Missense Mutation (SNP) | VAF 93/933 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DMD | c.3649C>T p.L1217F | Missense Mutation (SNP) | VAF 125/588 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DNAH9 | c.11395G>A p.G3799R | Missense Mutation (SNP) | VAF 61/523 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EPOR | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 38/431 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.047); called by muse, mutect2
- GRIN2A | c.4025C>T p.S1342F | Missense Mutation (SNP) | VAF 115/969 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- HECW1 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 105/817 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IQCH | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 81/807 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IQGAP2 | c.3357T>A p.F1119L | Missense Mutation (SNP) | VAF 92/1032 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- ITGB4 | c.240G>A p.M80I | Missense Mutation (SNP) | VAF 62/400 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ITGB4 | c.1003-1G>A p.X335_splice | Splice Site (SNP) | VAF 36/360 reads (10%) | called by muse, mutect2, varscan2
- ITIH3 | c.2524C>T p.H842Y | Missense Mutation (SNP) | VAF 58/536 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.393); called by muse, mutect2, varscan2
- KIF1B | c.5055A>T p.E1685D (on ENST00000377086 / NM_001365952.1; = p.E1639D on NM_015074.3) | Missense Mutation (SNP) | VAF 118/994 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MAK | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 68/646 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAP3K15 | c.2813G>A p.G938E | Missense Mutation (SNP) | VAF 77/295 reads (26%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- MFSD2A | c.458C>T p.P153L (on ENST00000372809 / NM_001136493.3; = p.P140L on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 95/825 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- MYLK3 | c.1456G>A p.V486I | Missense Mutation (SNP) | VAF 36/403 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.007); called by muse, mutect2
- MYRFL | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 106/1082 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.052); called by muse, mutect2
- NOD2 | c.3035C>T p.T1012I | Missense Mutation (SNP) | VAF 71/592 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- NOMO2 | c.2273+1G>A p.X758_splice | Splice Site (SNP) | VAF 25/474 reads (5%) | called by muse, mutect2
- PHF8 | c.2071C>T p.R691C (on ENST00000357988 / NM_001184896.1; = p.R655C on NM_015107.3) | Missense Mutation (SNP) | VAF 129/624 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLA2G4D | c.322C>T p.L108F | Missense Mutation (SNP) | VAF 69/573 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRSS54 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 68/752 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0.006); called by muse, mutect2
- PTPDC1 | c.275C>T p.A92V (on ENST00000375360 / NM_177995.3; = p.A144V on NM_152422.4) | Missense Mutation (SNP) | VAF 48/417 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN4 | c.1861C>T p.Q621* | Nonsense Mutation (SNP) | VAF 100/1005 reads (10%) | called by muse, mutect2
- RAVER2 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 166/1381 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RIPK1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 48/508 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2
- RPAP2 | c.471G>A p.W157* | Nonsense Mutation (SNP) | VAF 128/1169 reads (11%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.89-7C>T | Splice Region (SNP) | VAF 76/863 reads (9%) | called by muse, mutect2
- SCGB2A2 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 58/521 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SEC63 | c.983A>C p.K328T | Missense Mutation (SNP) | VAF 101/1017 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX14 | c.1238C>T p.P413L (on ENST00000314673 / NM_001350535.1; = p.P369L on NM_020468.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 126/1218 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- STK36 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 79/701 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SULF2 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 55/551 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TAOK2 | c.808C>T p.P270S | Missense Mutation (SNP) | VAF 54/582 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- TAS1R2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 82/793 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRIM49 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 92/1942 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.14); called by muse, mutect2
- TTC6 | c.2677G>A p.E893K | Missense Mutation (SNP) | VAF 82/871 reads (9%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.462); called by muse, mutect2
- TWIST1 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- ACSM3 | c.468G>A p.Q156= | Silent (SNP) | VAF 90/907 reads (10%) | called by muse, mutect2, varscan2
- ANHX | c.918C>T p.F306= | Silent (SNP) | VAF 63/489 reads (13%) | called by muse, mutect2, varscan2
- BANF2 | c.120C>T p.I40= | Silent (SNP) | VAF 44/420 reads (10%) | catalogued as COSV99856526; called by muse, mutect2, varscan2
- BLNK | c.741G>A p.R247= | Silent (SNP) | VAF 62/636 reads (10%) | catalogued as rs782808467, COSV56409014; called by muse, mutect2, varscan2
- CARMIL3 | c.165C>T p.F55= | Silent (SNP) | VAF 54/611 reads (9%) | called by muse, mutect2
- CCHCR1 | c.1159C>T p.L387= | Silent (SNP) | VAF 73/672 reads (11%) | catalogued as COSV66183231; called by muse, mutect2, varscan2
- CDC14A | c.480C>T p.D160= | Silent (SNP) | VAF 98/1078 reads (9%) | called by muse, mutect2
- CDH6 | c.1329G>A p.S443= | Silent (SNP) | VAF 147/1241 reads (12%) | catalogued as rs142200699; called by muse, mutect2, varscan2
- CDK13 | c.1327C>T p.L443= | Silent (SNP) | VAF 112/953 reads (12%) | called by muse, mutect2, varscan2
- CNGB3 | c.2004G>A p.P668= | Silent (SNP) | VAF 121/1186 reads (10%) | catalogued as rs142347723; ClinVar: likely benign; called by muse, mutect2, varscan2
- CPAMD8 | c.849C>T p.P283= (on ENST00000651564; = p.P236= on NM_015692.5) | Silent (SNP) | VAF 43/429 reads (10%) | catalogued as rs767670758; called by muse, mutect2, varscan2
- CTNNA3 | c.375C>T p.A125= | Silent (SNP) | VAF 138/1210 reads (11%) | called by muse, mutect2, varscan2
- CWH43 | c.1674G>A p.R558= | Silent (SNP) | VAF 56/706 reads (8%) | catalogued as COSV56935893; called by muse, mutect2
- DLG4 | c.636C>T p.I212= (on ENST00000399506 / NM_001321075.3; = p.I255= on NM_001365.4) | Silent (SNP) | VAF 37/302 reads (12%) | called by muse, mutect2, varscan2
- DLG5 | c.5676C>T p.A1892= | Silent (SNP) | VAF 42/644 reads (7%) | called by muse, mutect2
- DMBX1 | c.547C>T p.L183= | Silent (SNP) | VAF 74/628 reads (12%) | called by muse, mutect2, varscan2
- DNAH1 | c.9609C>T p.I3203= | Silent (SNP) | VAF 54/541 reads (10%) | called by muse, mutect2
- EPHA1 | c.2244G>A p.R748= | Silent (SNP) | VAF 53/477 reads (11%) | called by muse, mutect2, varscan2
- ERG | c.531G>A p.K177= | Silent (SNP) | VAF 90/681 reads (13%) | called by muse, mutect2, varscan2
- GSE1 | c.3231C>T p.P1077= | Silent (SNP) | VAF 96/690 reads (14%) | called by muse, mutect2, varscan2
- HPRT1 | c.204C>T p.L68= | Silent (SNP) | VAF 79/339 reads (23%) | called by muse, mutect2, varscan2
- IP6K2 | c.1023C>T p.P341= | Silent (SNP) | VAF 108/827 reads (13%) | catalogued as rs768166028; called by muse, mutect2, varscan2
- JCAD | c.3264G>A p.R1088= | Silent (SNP) | VAF 26/289 reads (9%) | catalogued as rs1027245491, COSV64761036; called by muse, mutect2
- KBTBD11 | c.1326C>T p.P442= | Silent (SNP) | VAF 20/276 reads (7%) | catalogued as rs1331529027; called by muse, mutect2
- KIF21B | c.2530C>T p.L844= | Silent (SNP) | VAF 72/540 reads (13%) | called by muse, mutect2, varscan2
- LAMB3 | c.426C>T p.T142= | Silent (SNP) | VAF 96/756 reads (13%) | called by muse, mutect2, varscan2
- MC3R | c.495C>T p.I165= | Silent (SNP) | VAF 78/716 reads (11%) | catalogued as COSV54764907; called by muse, mutect2, varscan2
- MISP | c.541C>T p.L181= | Silent (SNP) | VAF 21/161 reads (13%) | catalogued as rs778897192; called by muse, mutect2, varscan2
- NPEPPS | c.1941C>T p.P647= | Silent (SNP) | VAF 80/713 reads (11%) | called by muse, mutect2, varscan2
- PARVB | c.873C>T p.L291= | Silent (SNP) | VAF 64/567 reads (11%) | called by muse, mutect2, varscan2
- PCNT | c.8298C>T p.L2766= | Silent (SNP) | VAF 53/546 reads (10%) | catalogued as rs779372343; called by muse, mutect2
- PELI2 | c.429C>T p.I143= | Silent (SNP) | VAF 83/1076 reads (8%) | catalogued as rs368097050; called by muse, mutect2
- PRMT6 | c.973C>T p.L325= | Silent (SNP) | VAF 48/394 reads (12%) | called by muse, mutect2, varscan2
- PRSS1 | c.141C>T p.F47= | Silent (SNP) | VAF 85/866 reads (10%) | called by muse, mutect2
- PTPDC1 | c.276C>T p.A92= (on ENST00000375360 / NM_177995.3; = p.A144= on NM_152422.4) | Silent (SNP) | VAF 48/422 reads (11%) | called by muse, mutect2, varscan2
- RECQL4 | c.3186G>A p.R1062= | Silent (SNP) | VAF 59/553 reads (11%) | called by muse, mutect2, varscan2
- SCYL1 | c.1161C>T p.T387= | Silent (SNP) | VAF 78/800 reads (10%) | catalogued as COSV54214413; called by muse, mutect2
- SDK1 | c.1185G>A p.R395= | Silent (SNP) | VAF 71/826 reads (9%) | called by muse, mutect2
- SORCS3 | c.2310C>T p.F770= | Silent (SNP) | VAF 130/963 reads (13%) | catalogued as COSV100863457, COSV63795244; called by muse, mutect2, varscan2
- SOX6 | c.1512G>A p.R504= (on ENST00000528429 / NM_001145819.2; = p.R477= on NM_017508.3) | Silent (SNP) | VAF 110/1004 reads (11%) | catalogued as rs1431841522, COSV100322205; called by muse, mutect2, varscan2
- SPTBN5 | c.10332G>A p.L3444= | Silent (SNP) | VAF 50/379 reads (13%) | catalogued as rs1567181487; called by muse, mutect2, varscan2
- SPTBN5 | c.2337C>T p.A779= | Silent (SNP) | VAF 42/301 reads (14%) | called by muse, mutect2, varscan2
- SRCAP | c.6888C>T p.S2296= | Silent (SNP) | VAF 43/504 reads (9%) | catalogued as rs550188188, COSV99351589; called by muse, mutect2
- SRP72 | c.1131G>A p.L377= | Silent (SNP) | VAF 110/1069 reads (10%) | called by muse, mutect2, varscan2
- STARD9 | c.12246C>T p.L4082= | Silent (SNP) | VAF 50/584 reads (9%) | called by muse, mutect2
- SULF2 | c.1788C>T p.P596= | Silent (SNP) | VAF 55/551 reads (10%) | catalogued as rs752223390; called by muse, mutect2, varscan2
- TBATA | c.529C>T p.L177= | Silent (SNP) | VAF 69/705 reads (10%) | called by muse, mutect2
- TP63 | c.453G>A p.Q151= | Silent (SNP) | VAF 53/454 reads (12%) | catalogued as COSV53197364, COSV53200437; called by muse, mutect2, varscan2
- TRIM39 | c.1128C>T p.F376= | Silent (SNP) | VAF 70/567 reads (12%) | called by muse, mutect2, varscan2
- TSEN54 | c.534C>T p.S178= | Silent (SNP) | VAF 45/398 reads (11%) | called by muse, mutect2, varscan2
- UNC13B | c.2064C>T p.F688= | Silent (SNP) | VAF 76/918 reads (8%) | catalogued as COSV65937967; called by muse, mutect2
- UNC80 | c.2682A>G p.Q894= | Silent (SNP) | VAF 126/1103 reads (11%) | called by muse, mutect2, varscan2
- ZAR1L | c.267G>A p.K89= | Silent (SNP) | VAF 67/554 reads (12%) | called by muse, mutect2, varscan2
- ZNF541 | c.1953G>A p.L651= | Silent (SNP) | VAF 31/321 reads (10%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-7689C>T | Intron (SNP) | VAF 96/877 reads (11%) | catalogued as rs1279271757; called by muse, mutect2, varscan2
- ACSL6 | c.915+60G>A | Intron (SNP) | VAF 41/326 reads (13%) | called by muse, mutect2, varscan2
- ANO4 | c.-61_-54del | 5'UTR (DEL) | VAF 26/210 reads (12%) | called by mutect2, varscan2
- AP2M1 | c.74+525C>G | Intron (SNP) | VAF 76/797 reads (10%) | catalogued as rs1429839040; called by muse, mutect2
- BCAS3 | c.1487-11914C>T | Intron (SNP) | VAF 92/1185 reads (8%) | called by muse, mutect2
- CALML3 | c.*89C>T | 3'UTR (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- CES5A | c.551+26C>T | Intron (SNP) | VAF 32/253 reads (13%) | called by muse, mutect2, varscan2
- COL20A1 | c.2807-12C>A | Intron (SNP) | VAF 61/624 reads (10%) | called by muse, mutect2
- CWH43 | c.*71T>A | 3'UTR (SNP) | VAF 37/280 reads (13%) | called by muse, mutect2, varscan2
- DAXX | c.-153C>T | 5'UTR (SNP) | VAF 33/231 reads (14%) | catalogued as COSV99802239; called by muse, mutect2, varscan2
- DNASE1 | chr16:3662980 A>G | 3'Flank (SNP) | VAF 16/153 reads (10%) | called by muse, mutect2
- FAM53C | chr5:138338091 C>T | 5'Flank (SNP) | VAF 54/626 reads (9%) | called by muse, mutect2
- GP9 | c.*44C>T | 3'UTR (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- HECTD4 | c.13114+44C>T | Intron (SNP) | VAF 28/184 reads (15%) | called by muse, mutect2, varscan2
- LTC4S | c.311+14G>A | Intron (SNP) | VAF 34/276 reads (12%) | catalogued as rs1304297751; called by muse, mutect2, varscan2
- MAPK3 | chr16:30123222 C>T | 5'Flank (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- MAPK3 | chr16:30123223 C>T | 5'Flank (SNP) | VAF 6/93 reads (6%) | called by muse, mutect2
- MED31 | chr17:6651614 C>T | 5'Flank (SNP) | VAF 19/139 reads (14%) | catalogued as rs867138329, COSV56725715; called by muse, mutect2, varscan2
- MERTK | c.1786+30T>A | Intron (SNP) | VAF 73/699 reads (10%) | called by muse, mutect2, varscan2
- MUC19 | n.5485C>G | RNA (SNP) | VAF 80/1052 reads (8%) | catalogued as rs1213639192; called by muse, mutect2
- OR1N2 | c.*38C>T | 3'UTR (SNP) | VAF 30/170 reads (18%) | catalogued as rs764376279; called by muse, mutect2, varscan2
- PFKL | c.1192-10C>T | Intron (SNP) | VAF 48/679 reads (7%) | catalogued as rs763676702; called by muse, mutect2
- PSMB5 | c.*13G>A | 3'UTR (SNP) | VAF 17/152 reads (11%) | catalogued as rs113091841; called by muse, varscan2
- RIMBP2 | c.2361+18G>A | Intron (SNP) | VAF 31/282 reads (11%) | called by muse, mutect2, varscan2
- RNF149 | c.864-59C>A | Intron (SNP) | VAF 34/180 reads (19%) | called by muse, mutect2, varscan2
- SCN5A | c.612-291G>A | Intron (SNP) | VAF 19/150 reads (13%) | catalogued as rs1311612491; called by muse, mutect2, varscan2
- SLC37A2 | c.1490+129C>T | Intron (SNP) | VAF 43/285 reads (15%) | called by muse, mutect2, varscan2
- SPAST | c.-51C>T | 5'UTR (SNP) | VAF 8/44 reads (18%) | called by muse, mutect2, varscan2
- TBC1D8B | c.1838-702G>A | Intron (SNP) | VAF 72/399 reads (18%) | catalogued as rs771590895; called by muse, mutect2, varscan2
- TCP1 | c.489-14A>T | Intron (SNP) | VAF 42/414 reads (10%) | called by muse, mutect2, varscan2
- TNS2 | c.3575-65C>T | Intron (SNP) | VAF 11/77 reads (14%) | called by muse, mutect2, varscan2
- UBE2V2 | c.16+32C>T | Intron (SNP) | VAF 18/83 reads (22%) | catalogued as rs1490304773, COSV72878793; called by muse, mutect2, varscan2
- ZNRF1 | c.-16C>T | 5'UTR (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- ZP1 | c.827-12C>T | Intron (SNP) | VAF 51/429 reads (12%) | catalogued as rs774929342; called by muse, mutect2, varscan2
